Somatic mutation profile of tumor specimen TCGA-BG-A0MC-01A (aliquot TCGA-BG-A0MC-01A-21W-A062-09) from TCGA case TCGA-BG-A0MC, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G1; Age at diagnosis: 74.3 years (27,136 days).
Specimen TCGA-BG-A0MC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5dda348c-3b12-42f7-9445-846201d0501e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BG-A0MC-10A (Blood Derived Normal), aliquot TCGA-BG-A0MC-10A-01W-A062-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/35bb2f9c-2d6e-4605-9b9e-0fa41a63bb1d

The open-access MAF lists 60 somatic variants for this specimen: 49 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 43, Silent 11, Frame Shift Del 3, In Frame Del 1, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 5/25 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1625A>C p.E542A | Missense Mutation (SNP) | VAF 17/74 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen possibly damaging (0.883); catalogued as rs1057519927, COSV55876800, COSV55881194, COSV55893680; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AGL | c.2564A>G p.H855R | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.045); catalogued as rs754642543, COSV54049081, COSV54055724; called by muse, mutect2, varscan2
- ARID5B | c.1399-2A>G p.X467_splice | Splice Site (SNP) | VAF 56/170 reads (33%) | catalogued as COSV54415883, COSV54429251; called by muse, mutect2, varscan2
- CACNA1A | c.1444C>T p.R482C | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs377011125, COSV100801940; called by muse, mutect2, varscan2
- CDC5L | c.1235C>T p.P412L | Missense Mutation (SNP) | VAF 9/277 reads (3%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.871); catalogued as COSV65175551; called by muse, mutect2
- CTCF | c.1133C>T p.P378L | Missense Mutation (SNP) | VAF 73/254 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50462744; called by muse, mutect2, varscan2
- CTSV | c.853G>A p.G285S | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs551605839, COSV52344196; called by muse, mutect2, varscan2
- ELL2 | c.1214G>A p.R405Q | Missense Mutation (SNP) | VAF 65/189 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0.267); catalogued as rs751389108, COSV52981481; called by muse, mutect2, varscan2
- EMB | c.712C>T p.R238C | Missense Mutation (SNP) | VAF 59/185 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as rs749613196, COSV57481029; called by muse, mutect2, varscan2
- FANCA | c.2890C>T p.L964F | Missense Mutation (SNP) | VAF 18/173 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.088); catalogued as COSV59795920; called by muse, mutect2
- GLI2 | c.3403G>A p.G1135S (on ENST00000361492 / NM_001374353.1; = p.G1152S on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58036642; called by muse, mutect2
- GLIS3 | c.1445G>A p.R482H | Missense Mutation (SNP) | VAF 43/151 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1413199045, COSV60925523; called by muse, mutect2, varscan2
- GOLGA4 | c.4285A>G p.I1429V | Missense Mutation (SNP) | VAF 79/256 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV62709679; called by muse, mutect2, varscan2
- GPR158 | c.476C>A p.A159E | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66266696; called by muse, mutect2
- GREB1 | c.5279A>G p.N1760S | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs765158897, COSV52182676; called by muse, mutect2, varscan2
- GRIA1 | c.2513G>A p.R838Q | Missense Mutation (SNP) | VAF 82/272 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.136); catalogued as rs779724339, COSV53592809; called by muse, mutect2, varscan2
- GRM8 | c.656C>T p.S219L | Missense Mutation (SNP) | VAF 42/146 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs772324014, COSV58803533; called by muse, mutect2, varscan2
- KBTBD4 | c.1123A>T p.N375Y | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.93); catalogued as COSV58596810; called by muse, mutect2, varscan2
- LPAR2 | c.662G>A p.R221H | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.956); catalogued as rs376879365; called by muse, mutect2
- LRRC7 | c.4711C>T p.R1571C (on ENST00000651989 / NM_001370785.2; = p.R1491C on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/61 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs909071809, COSV50420690; called by muse, mutect2
- MAGEL2 | c.3746G>A p.R1249H | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0.005); catalogued as rs745776063, COSV100045925, COSV58566257; ClinVar: likely benign; called by muse, mutect2, varscan2
- MORN1 | c.941G>A p.G314E | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66002681; called by muse, mutect2
- MTOR | c.3716G>A p.S1239N | Missense Mutation (SNP) | VAF 264/428 reads (62%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs868768181, COSV63869152; called by muse, mutect2, varscan2
- MYO1B | c.1501A>G p.N501D | Missense Mutation (SNP) | VAF 125/453 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.266); catalogued as COSV58428407; called by muse, mutect2, varscan2
- NOC3L | c.1643G>T p.G548V | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV64929684; called by muse, mutect2, varscan2
- NR2C1 | c.1269A>G p.I423M | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV58008980; called by muse, mutect2, varscan2
- PCK1 | c.1141G>A p.V381I | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as rs766917599, COSV60126703; called by muse, mutect2, varscan2
- PLEKHA4 | c.28C>G p.L10V | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.987); catalogued as rs1160856687, COSV52338491; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.1730C>T p.A577V | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.12); catalogued as rs776329867, COSV53451331; called by mutect2, varscan2
- PTEN | c.155del p.D52Vfs*2 | Frame Shift Del (DEL) | VAF 56/190 reads (29%) | catalogued as CD075524, CM110147, COSV64292079, COSV64310362; called by mutect2, pindel, varscan2
- RC3H1 | c.2690A>G p.Q897R | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); catalogued as COSV51198340; called by muse, mutect2, varscan2
- RFWD3 | c.490G>A p.G164R | Missense Mutation (SNP) | VAF 39/142 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.048); catalogued as rs145324335, COSV99077040; called by muse, mutect2, varscan2
- SH3PXD2A | c.1798C>T p.R600W (on ENST00000369774 / NM_001365079.1; = p.R572W on NM_014631.2) | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.895); catalogued as rs772194389, COSV60116143; called by muse, mutect2, varscan2
- SLC25A39 | c.592del p.E198Sfs*43 (on ENST00000377095 / NM_001143780.3; = p.E190Sfs*43 on NM_016016.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 4/15 reads (27%) | catalogued as rs745454989; called by mutect2, varscan2
- SPTBN2 | c.4922C>T p.A1641V | Missense Mutation (SNP) | VAF 44/165 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as rs376009552; called by muse, mutect2, varscan2
- SRRM1 | c.2572G>A p.A858T | Missense Mutation (SNP) | VAF 35/62 reads (56%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV60475736; called by muse, mutect2, varscan2
- STXBP1 | c.435T>A p.Y145* | Nonsense Mutation (SNP) | VAF 45/166 reads (27%) | catalogued as COSV64812354; called by muse, mutect2, varscan2
- TNIP3 | c.261C>A p.S87R | Missense Mutation (SNP) | VAF 70/230 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV50246213; called by muse, mutect2, varscan2
- TRPM6 | c.4247G>T p.G1416V | Missense Mutation (SNP) | VAF 73/255 reads (29%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.01); catalogued as COSV62504610; called by muse, mutect2, varscan2
- TUBB4A | c.925C>T p.R309C | Missense Mutation (SNP) | VAF 47/164 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.186); catalogued as rs1386587020, COSV51152536; called by muse, mutect2, varscan2
- WIZ | c.4259G>A p.R1420Q (on ENST00000673675 / NM_001371589.1; = p.R325Q on NM_021241.3) | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.419); catalogued as rs748526882, COSV54605324; called by muse, mutect2, varscan2
- XPO4 | c.556T>C p.C186R | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as COSV55005245; called by muse, mutect2, varscan2
- ZNF229 | c.1703G>T p.G568V | Missense Mutation (SNP) | VAF 63/201 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV52160440; called by muse, mutect2, varscan2
- ZNF337 | c.457G>C p.E153Q | Missense Mutation (SNP) | VAF 84/319 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs758745403, COSV53320536; called by muse, mutect2, varscan2
- ZNF592 | c.2858C>T p.A953V | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV55435526; called by muse, varscan2
- ZNF883 | c.1121A>G p.K374R | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs866321263, COSV71308930; called by muse, mutect2, varscan2
- PTEN | c.175_176delinsA p.S59Kfs*40 | Frame Shift Del (DEL) | VAF 13/53 reads (25%) | called by pindel, varscan2*
- TLE1 | c.2164_2166del p.L722del | In Frame Del (DEL) | VAF 22/91 reads (24%) | called by pindel, varscan2
- ABCA10 | c.525A>G p.A175= | Silent (SNP) | VAF 43/156 reads (28%) | catalogued as COSV52219360; called by muse, mutect2, varscan2
- CHST5 | c.954G>A p.T318= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs373714892; called by muse, mutect2
- DCUN1D1 | c.21G>A p.S7= | Silent (SNP) | VAF 35/106 reads (33%) | catalogued as rs754937408, COSV53043909; called by muse, mutect2, varscan2
- LIMA1 | c.930C>T p.P310= | Silent (SNP) | VAF 90/325 reads (28%) | catalogued as COSV57964398; called by muse, mutect2, varscan2
- NEUROG3 | c.381C>T p.F127= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as COSV54342409; called by muse, mutect2, varscan2
- PCDHGA11 | c.1563C>T p.F521= | Silent (SNP) | VAF 35/120 reads (29%) | catalogued as COSV53912817; called by muse, mutect2, varscan2
- SLC49A4 | c.1188C>T p.S396= | Silent (SNP) | VAF 55/159 reads (35%) | catalogued as rs150962928; called by muse, mutect2, varscan2
- TACR3 | c.510C>T p.F170= | Silent (SNP) | VAF 41/134 reads (31%) | catalogued as rs767212232, COSV59199235; called by muse, mutect2, varscan2
- TDRD6 | c.4035C>T p.P1345= | Silent (SNP) | VAF 104/270 reads (39%) | catalogued as rs750220784, COSV60174391; called by muse, mutect2, varscan2
- VANGL2 | c.1329G>A p.A443= | Silent (SNP) | VAF 46/130 reads (35%) | catalogued as rs146767141; called by muse, mutect2, varscan2
- ZBBX | c.813C>T p.T271= | Silent (SNP) | VAF 80/284 reads (28%) | catalogued as rs375095384; called by muse, mutect2
